CCDI case PBCHJU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a9e83ff8-a5f1-406d-982c-ee00e6a205af

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,155 days).

Biospecimens (3 samples)
- Sample 0DSBXU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSBYD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSCOT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
